Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A4NA, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A4NA-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site, Liver C22.0

gw/2/24/12

REVISED REPORT (Revised information underlined)

Addendum/Procedure included

DIAGNOSIS:

D. Liver, left lobe, resection: Poorly differentiated hepatocellular carcinoma forming a lobulated mass, 9.6 x 9.5 x 9.3 cm. There is extensive lymphovascular invasion including a tumor thrombus. The margins are negative for tumor by < 0.1 cm. Multiple (1 caval and 1 hilar) regional lymph nodes are negative for tumor.

A. Lymph nodes, celiac artery, excision: Multiple (3) celiac artery lymph nodes are negative for tumor.

B. Lymph node, hepatic artery, excision: A single (1) hepatic artery lymph node is negative for tumor.

C. Lymph node, pericholedochal, excision: A single (1) pericholedochal lymph node is negative for tumor.

Photographed.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

ADDENDUM:

In situ hybridization for albumin is positive.

AMENDMENTS: (Previous Signout Date

Revision Description: Removed "favor bile duct primary" from the original diagnosis.

....Previous Diagnosis....

D. Liver, left lobe, resection: Poorly differentiated hepatocellular carcinoma, favor bile duct primary, forming a lobulated mass, 9.6 x 9.5 x 9.3 cm. There is extensive lymphovascular invasion including a tumor thrombus. The margins are negative for tumor by < 0.1 cm. Multiple (1 caval and 1 hilar) regional lymph nodes are negative for tumor.

A. Lymph nodes, celiac artery, excision: Multiple (3) celiac artery lymph nodes are negative for tumor.

B. Lymph node, hepatic artery, excision: A single (1) hepatic artery lymph node is negative for tumor.

C. Lymph node, pericholedochal, excision: A single (1) pericholedochal lymph node is negative for tumor.

Photographed.

[page 2 of 2]
This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

***Signing Pathologist'

AMENDMENTS: (Previous Signout Date:

Revision Description: Special stains support hepatocellular carcinoma for part D. Diagnosis changed to reflect this.

....Original Diagnosis....

D. Liver, left lobe, resection: Poorly differentiated adenocarcinoma, favor bile duct primary, forming a lobulated mass, 9.6 x 9.5 x 9.3 cm. There is extensive lymphovascular invasion including a tumor thrombus. The margins are negative for tumor by < 0.1 cm. Multiple (1 caval and 1 hilar) regional lymph nodes are negative for tumor.

A. Lymph nodes, celiac artery, excision: Multiple (3) celiac artery lymph nodes are negative for tumor.

B. Lymph node, hepatic artery, excision: A single (1) hepatic artery lymph node is negative for tumor.

C. Lymph node, pericholedochal, excision: A single (1) pericholedochal lymph node is negative for tumor.

Photographed.

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

Source: NCI Genomic Data Commons file 46d9bcc7-0d5b-43a4-9228-2ff03d441571 (TCGA-DD-A4NA.48C11C04-947E-4954-9687-DF275D897F79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).